Somatic mutation profile of tumor specimen TCGA-19-5954-01A (aliquot TCGA-19-5954-01A-11D-1696-08) from TCGA case TCGA-19-5954, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 72.2 years (26,355 days).
Specimen TCGA-19-5954-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 43431479-a3be-4726-ab30-82b2f8be2fff.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-19-5954-10A (Blood Derived Normal), aliquot TCGA-19-5954-10A-01D-1696-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d1c7b272-3f64-42d1-9bab-02d590a8796b

The open-access MAF lists 87 somatic variants for this specimen: 63 protein-altering or splice-affecting, 24 silent.
By variant classification: Missense Mutation 53, Silent 24, Nonsense Mutation 5, In Frame Del 2, Splice Region 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.332A>G p.K111R | Missense Mutation (SNP) | VAF 34/123 reads (28%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as rs1057519935, COSV55961186; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCB1 | c.2873G>A p.R958Q | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.281); catalogued as rs144369247; called by muse, mutect2, varscan2
- ABHD8 | c.598C>T p.R200C | Missense Mutation (SNP) | VAF 51/159 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs371098180, COSV53113154; called by muse, mutect2, varscan2
- AC004593.2 | c.349A>G p.R117G | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.985); catalogued as COSV56099551; called by muse, mutect2, varscan2
- ADCY3 | c.215G>A p.R72K | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.079); catalogued as COSV53171538; called by muse, mutect2, varscan2
- ADNP2 | c.1754G>A p.G585D | Missense Mutation (SNP) | VAF 36/87 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.494); catalogued as rs773368425, COSV51541130; called by muse, mutect2, varscan2
- ALDH6A1 | c.872T>C p.V291A | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.876); catalogued as COSV63246901; called by muse, mutect2, varscan2
- APLP2 | c.1384G>A p.A462T | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53842733; called by muse, mutect2, varscan2
- ARMCX5 | c.943del p.V316Lfs*6 | Frame Shift Del (DEL) | VAF 30/106 reads (28%) | catalogued as COSV55767170; called by pindel, varscan2
- ARMCX5 | c.960G>C p.K320N | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.928); catalogued as COSV55767182; called by muse, varscan2
- BCHE | c.1618A>G p.T540A | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT tolerated (0.73); PolyPhen benign (0.003); catalogued as COSV52259913; called by muse, mutect2, varscan2
- CCDC88C | c.4336G>A p.A1446T | Missense Mutation (SNP) | VAF 39/163 reads (24%) | SIFT tolerated (0.59); PolyPhen benign (0.024); catalogued as COSV100484992; called by muse, mutect2
- CDK13 | c.2816C>T p.P939L | Missense Mutation (SNP) | VAF 54/193 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51703695; called by muse, mutect2, varscan2
- CENPF | c.6265G>A p.V2089I | Missense Mutation (SNP) | VAF 41/91 reads (45%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as rs754606834, COSV65277245; called by muse, mutect2, varscan2
- CENPI | c.962A>G p.E321G | Missense Mutation (SNP) | VAF 49/121 reads (40%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV54504798; called by muse, mutect2, varscan2
- CHD9 | c.4940A>T p.Q1647L | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.075); catalogued as COSV54614899; called by muse, mutect2, varscan2
- CIB1 | c.140C>T p.S47L | Missense Mutation (SNP) | VAF 42/108 reads (39%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as rs369465701; called by muse, mutect2, varscan2
- CLYBL | c.73C>G p.L25V | Missense Mutation (SNP) | VAF 41/122 reads (34%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.015); catalogued as COSV59225679; called by muse, mutect2, varscan2
- CPAMD8 | c.4112G>A p.R1371H (on ENST00000651564; = p.R1324H on NM_015692.5) | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs746971695, COSV71596347; called by muse, mutect2, varscan2
- DGAT2L6 | c.409T>A p.F137I | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT tolerated (0.08); PolyPhen benign (0.109); catalogued as COSV60718323; called by muse, mutect2, varscan2
- DNAJC11 | c.995G>A p.G332E | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as COSV53788178, COSV53788942; called by muse, mutect2, varscan2
- ERG | c.365C>T p.P122L | Missense Mutation (SNP) | VAF 27/63 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV55736564; called by muse, mutect2, varscan2
- F2 | c.1411C>G p.P471A | Missense Mutation (SNP) | VAF 47/123 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs377462682, COSV61314662; called by muse, mutect2, varscan2
- FBLIM1 | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 34/94 reads (36%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.584); catalogued as COSV60030862; called by muse, mutect2, varscan2
- FLG | c.10810G>A p.E3604K | Missense Mutation (SNP) | VAF 54/392 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.391); catalogued as CM112017, COSV100911362, COSV64246786; called by mutect2, varscan2
- GABRB3 | c.835G>A p.G279R | Missense Mutation (SNP) | VAF 27/62 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54671620; called by muse, mutect2, varscan2
- GPR34 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1393417949, COSV59372109; called by muse, mutect2, varscan2
- GRIP2 | c.2066G>A p.S689N (on ENST00000619221; = p.S592N on NM_001080423.4) | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV56123888; called by muse, mutect2, varscan2
- HTR1A | c.1192G>A p.V398I | Missense Mutation (SNP) | VAF 136/344 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV60500635; called by muse, mutect2, varscan2
- IDO2 | c.223A>T p.K75* (on ENST00000389060; = p.K88* on NM_194294.2) | Nonsense Mutation (SNP) | VAF 4/16 reads (25%) | catalogued as COSV58428244; called by muse, mutect2, varscan2
- IL27RA | c.220C>T p.R74C | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.332); catalogued as rs201645440, COSV54602158; called by muse, mutect2, varscan2
- KIF4B | c.2363G>A p.R788Q | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.08); PolyPhen benign (0.018); catalogued as rs370994878; called by muse, mutect2, varscan2
- KIR3DL1 | c.502G>A p.V168I | Missense Mutation (SNP) | VAF 85/215 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs200785070; called by muse, mutect2, varscan2
- KLK5 | c.604A>G p.K202E | Missense Mutation (SNP) | VAF 35/77 reads (45%) | SIFT tolerated (0.19); PolyPhen benign (0.029); catalogued as rs765507937, COSV60451047; called by muse, mutect2, varscan2
- LAMB3 | c.2740G>A p.E914K | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.013); catalogued as rs779175415, COSV50524187; called by muse, mutect2, varscan2
- LGALS14 | c.58G>A p.V20M | Missense Mutation (SNP) | VAF 86/222 reads (39%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as rs199912882, COSV62373040; called by muse, mutect2, varscan2
- MFSD6L | c.41G>T p.G14V | Missense Mutation (SNP) | VAF 18/59 reads (31%) | SIFT tolerated (0.18); PolyPhen benign (0.038); catalogued as COSV61004543; called by muse, mutect2, varscan2
- MKI67 | c.3802C>T p.R1268* | Nonsense Mutation (SNP) | VAF 73/128 reads (57%) | catalogued as rs1347593985, COSV64075704; called by muse, mutect2, varscan2
- MUC16 | c.38321G>A p.R12774H | Missense Mutation (SNP) | VAF 35/100 reads (35%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0); catalogued as rs548938808, COSV67485780; called by muse, mutect2, varscan2
- MUC17 | c.10930A>G p.T3644A | Missense Mutation (SNP) | VAF 41/142 reads (29%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.949); catalogued as rs199996089, COSV60297118; called by muse, mutect2, varscan2
- MYOF | c.1519T>C p.Y507H | Missense Mutation (SNP) | VAF 45/72 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63708052; called by muse, mutect2, varscan2
- OR6V1 | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 91/300 reads (30%) | SIFT tolerated (1); PolyPhen benign (0.019); catalogued as rs757175682, COSV69237599; called by muse, mutect2, varscan2
- PASD1 | c.785C>A p.S262Y | Missense Mutation (SNP) | VAF 43/114 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.799); catalogued as COSV64854936, COSV64856591; called by muse, mutect2, varscan2
- PCDHA8 | c.1904G>A p.R635H | Missense Mutation (SNP) | VAF 88/218 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.913); catalogued as COSV65325437; called by muse, mutect2, varscan2
- PIK3CA | c.10C>T p.R4* | Nonsense Mutation (SNP) | VAF 24/52 reads (46%) | catalogued as rs1051397, COSV55961176; called by muse, mutect2, varscan2
- PTPRZ1 | c.2261A>G p.N754S | Missense Mutation (SNP) | VAF 49/201 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as rs1424646950, COSV66442080; called by muse, mutect2, varscan2
- RGS9 | c.1582G>A p.V528M | Missense Mutation (SNP) | VAF 71/187 reads (38%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.03); catalogued as rs1454426612, COSV52227581; called by muse, mutect2, varscan2
- SEC16B | c.211C>A p.H71N | Missense Mutation (SNP) | VAF 35/96 reads (36%) | SIFT tolerated (0.06); PolyPhen benign (0.014); catalogued as COSV57629169; called by muse, mutect2, varscan2
- SLITRK4 | c.1283G>A p.R428H | Missense Mutation (SNP) | VAF 37/131 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs782819249, COSV62023474; called by muse, mutect2, varscan2
- SREBF1 | c.1376C>A p.P459H | Missense Mutation (SNP) | VAF 25/58 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55418446; called by muse, mutect2, varscan2
- SYNE1 | c.12230A>G p.K4077R (on ENST00000367255 / NM_182961.4; = p.K4006R on NM_033071.3) | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.972); catalogued as COSV55047665; called by muse, mutect2, varscan2
- TBC1D32 | c.3406A>T p.K1136* | Nonsense Mutation (SNP) | VAF 108/274 reads (39%) | catalogued as COSV51549461, COSV99250146; called by muse, mutect2, varscan2
- THEMIS2 | c.649C>T p.R217C | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs375363209; called by muse, mutect2, varscan2
- TNFRSF9 | c.208G>T p.G70C | Missense Mutation (SNP) | VAF 66/200 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1399281402, COSV101097333, COSV66348694; called by muse, mutect2, varscan2
- TRIM71 | c.1006C>T p.R336* | Nonsense Mutation (SNP) | VAF 35/140 reads (25%) | catalogued as COSV67472031; called by muse, mutect2, varscan2
- TRPM6 | c.927C>A p.D309E | Missense Mutation (SNP) | VAF 42/97 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0.011); catalogued as COSV62517702; called by muse, mutect2, varscan2
- VAV1 | c.1132G>A p.E378K | Missense Mutation (SNP) | VAF 100/286 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.769); catalogued as COSV58388164; called by muse, mutect2, varscan2
- WDR1 | c.378G>A p.K126= | Splice Region (SNP) | VAF 4/12 reads (33%) | catalogued as COSV53331853, COSV53332624; called by muse, mutect2
- ZSCAN1 | c.944G>A p.R315H | Missense Mutation (SNP) | VAF 28/70 reads (40%) | SIFT tolerated (0.17); PolyPhen benign (0.433); catalogued as rs771707739, COSV56602345; called by muse, mutect2, varscan2
- CDKL2 | c.304G>C p.V102L | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- EMILIN3 | c.2090_2092del p.E697del | In Frame Del (DEL) | VAF 9/29 reads (31%) | called by mutect2, pindel, varscan2
- GDPD3 | c.261_263del p.D87del | In Frame Del (DEL) | VAF 24/86 reads (28%) | called by pindel, varscan2
- PLEKHA8 | c.481dup p.T161Nfs*20 | Frame Shift Ins (INS) | VAF 82/334 reads (25%) | called by mutect2, pindel, varscan2
- ADGRV1 | c.11346G>A p.A3782= | Silent (SNP) | VAF 10/20 reads (50%) | catalogued as rs375790811, COSV67993118; called by muse, mutect2, varscan2
- ALCAM | c.81A>T p.G27= | Silent (SNP) | VAF 32/71 reads (45%) | catalogued as COSV60251955; called by muse, mutect2, varscan2
- ALDH1A2 | c.132C>T p.N44= | Silent (SNP) | VAF 34/90 reads (38%) | catalogued as rs374228229; called by muse, mutect2, varscan2
- AOX1 | c.1521G>A p.A507= | Silent (SNP) | VAF 35/86 reads (41%) | catalogued as rs200716526; called by muse, mutect2, varscan2
- DCAF8L1 | c.99G>A p.T33= | Silent (SNP) | VAF 24/67 reads (36%) | catalogued as rs1176396699, COSV71595427; called by muse, mutect2, varscan2
- DUSP9 | c.1098G>A p.P366= | Silent (SNP) | VAF 34/79 reads (43%) | catalogued as rs782335794, COSV61438226; called by muse, mutect2, varscan2
- FAM111A | c.777A>G p.L259= | Silent (SNP) | VAF 51/117 reads (44%) | catalogued as rs768304259, COSV64655646; called by muse, mutect2, varscan2
- FBXO43 | c.1662A>G p.K554= | Silent (SNP) | VAF 19/51 reads (37%) | catalogued as rs1382035041, COSV71054943; called by muse, mutect2
- GABRD | c.1146C>T p.R382= | Silent (SNP) | VAF 22/57 reads (39%) | catalogued as rs374718450; called by muse, mutect2, varscan2
- HS3ST6 | c.567C>T p.S189= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as rs764098722, COSV53536447; called by muse, mutect2
- IGHV1-18 | c.324C>T p.D108= | Silent (SNP) | VAF 110/275 reads (40%) | catalogued as rs370164664; called by muse, mutect2, varscan2
- IL10RA | c.252C>T p.T84= | Silent (SNP) | VAF 36/101 reads (36%) | catalogued as rs763662644, COSV57141567; ClinVar: likely benign; called by muse, mutect2, varscan2
- LTBP2 | c.6G>A p.R2= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as COSV56212494; called by muse, mutect2, varscan2
- ME1 | c.465T>C p.R155= | Silent (SNP) | VAF 26/77 reads (34%) | catalogued as COSV63841314; called by muse, mutect2, varscan2
- MXRA5 | c.1371C>A p.T457= | Silent (SNP) | VAF 80/188 reads (43%) | catalogued as rs1201600302, COSV54243481; called by muse, mutect2, varscan2
- POFUT2 | c.894C>T p.F298= | Silent (SNP) | VAF 52/99 reads (53%) | catalogued as COSV57960309; called by muse, mutect2, varscan2
- PRDM13 | c.1992C>T p.D664= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as rs546224169, COSV65030423; called by muse, mutect2, varscan2
- RIOX2 | c.147C>A p.I49= | Silent (SNP) | VAF 34/107 reads (32%) | catalogued as COSV57724525; called by muse, varscan2
- SAMD9L | c.4101A>G p.L1367= | Silent (SNP) | VAF 82/347 reads (24%) | catalogued as COSV59083673; called by muse, mutect2, varscan2
- SERPINB2 | c.1032G>A p.S344= | Silent (SNP) | VAF 42/93 reads (45%) | catalogued as rs768454108, COSV53072240; called by muse, mutect2, varscan2
- SNX13 | c.1779G>A p.E593= | Silent (SNP) | VAF 47/190 reads (25%) | catalogued as COSV68067408; called by muse, mutect2, varscan2
- TRPM5 | c.1857C>T p.D619= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as rs145136134; called by muse, varscan2
- TUBA3D | c.885C>T p.C295= | Silent (SNP) | VAF 72/125 reads (58%) | catalogued as COSV58312682; called by mutect2, varscan2
- UTS2 | c.120G>A p.A40= | Silent (SNP) | VAF 25/70 reads (36%) | catalogued as rs759501467, COSV50013627; called by muse, mutect2, varscan2
